TCGA case TCGA-GN-A4U9 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Roswell. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab7eb3ec-bd87-4e49-9010-b51b17148f7c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 673 days (1.8 years).

Diagnoses (9)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: Progression; Age at diagnosis: 71.7 years (26,178 days); Days to diagnosis: 60 days; Prior treatment: No; Days to last follow up: 673 days (1.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,118 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Melphalan; Days to treatment start: 60 days; Days to treatment end: 60 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Days to treatment start: 165 days; Days to treatment end: 249 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Imiquimod; Days to treatment start: 384 days (1.1 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 408 days (1.1 years); Days to treatment end: 469 days (1.3 years); Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Axitinib; Days to treatment start: 523 days (1.4 years); Days to treatment end: 579 days (1.6 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 71.9 years (26,269 days); Days to diagnosis: 151 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
5. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 72.0 years (26,285 days); Days to diagnosis: 167 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 72.2 years (26,378 days); Days to diagnosis: 260 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 72.6 years (26,502 days); Days to diagnosis: 384 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease; Surgery, NOS, for progressive disease.
8. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 72.9 years (26,621 days); Days to diagnosis: 503 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
9. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 73.1 years (26,697 days); Days to diagnosis: 579 days (1.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (8 entries)
- Day 151 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 151 days.
- Day 167 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 167 days.
- Day 260 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 260 days.
- Day 384 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 384 days (1.1 years).
- Day 384 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 384 days (1.1 years).
- Day 503 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 503 days (1.4 years).
- Day 579 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 579 days (1.6 years).
- Days to follow up: 673 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 5.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 104 kg; Height: 176 cm; BMI: 33.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GN-A4U9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 170 mg.
  Slide TCGA-GN-A4U9-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-GN-A4U9-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GN-A4U9-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.7; Primary melanoma mitotic rate: 5; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment 4: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 673 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 673 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 151 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GN-A4U9-06A-11D-A32M-01): tumor purity 0.87, ploidy 3.13, whole-genome doublings 1.
